Gene-level copy-number profile of tumor specimen TCGA-XE-AANF-01A from TCGA case TCGA-XE-AANF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 27.0 years (9,854 days).
Specimen TCGA-XE-AANF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e63269ea-e99c-4a60-bf2b-309112b4fc8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/fedf33b3-7eba-4573-a60f-d730d3c7d1d5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2,017; copy number 1: 6,805; copy number 2: 15,930; copy number 3: 14,283; copy number 4: 11,149; copy number 5: 6,212; copy number 6: 1,696; copy number 7: 197; copy number 8: 561; copy number 86: 55.

Homozygous deletions (total copy number 0; autosomes only): 2,017 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:173,347,455–176,345,991, 59 genes: MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634, AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2, ARL2BPP6, DRD1, SFXN1, AC091393.1, RN7SKP148, HRH2, RNU6-226P, CPLX2, AC138965.2, AC138965.1, THOC3, THOC3-AS1, OR1X1P, AC139491.3, AC139491.1, FAM153B, AC139491.7, AC139491.5, AC139491.4, AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1, SIMC1, BRCC3P1.
- chr5:177,809,407–177,983,054, 7 genes (within-gene range 0–1): AC106795.1, OR1X5P, AC140125.3, AC106795.3, AC106795.2, AC106795.5, SUDS3P1.
- chr11:58,348,989–135,075,908, 1,945 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 813 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:190,077–33,576,200, 813 genes, copy number 7–86 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,293. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
